MMRF case MMRF_1569 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9aadd809-f84b-41b7-9b6a-11b914e9fb08

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.5 years (25,744 days); ISS stage: I; Days to last known disease status: 1,281 days (3.5 years); Days to last follow up: 1,281 days (3.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 429 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 616 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,222 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 4.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 61.7 g/L; Immunoglobulin A 0.231 g/L; Immunoglobulin M 0.269 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 11.4 g/dL; Glucose 4.9 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 86 (ECOG 0): M Protein 1.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.683 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.639 mg/dL; Immunoglobulin G 22.3 g/L; Immunoglobulin A 0.422 g/L; Immunoglobulin M 0.456 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.8 g/dL; Glucose 12.3 mmol/L.
- Day 156 (ECOG 0): M Protein 0.893 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 0.641 g/L; Immunoglobulin M 0.487 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 11 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.7 g/dL; Glucose 7.59 mmol/L.
- Day 240 (ECOG 0): M Protein 0.352 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.331 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 8.08 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 9.67 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 338 (ECOG 0): M Protein 0.207 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.491 mg/dL; Immunoglobulin G 7.77 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 3.8 mmol/L.
- Day 429 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.466 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 4.13 mmol/L.
- Day 518 (ECOG 0): M Protein 0.218 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.842 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.679 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 9.98 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.24 mmol/L.
- Day 616 (ECOG 0): M Protein 0.414 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 4.02 mmol/L.
- Day 679 (ECOG 0): M Protein 0.416 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.631 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.07 mmol/L.
- Day 765 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.673 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.961 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.29 mmol/L.
- Day 854 (ECOG 1): M Protein 0.454 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.07 mmol/L.
- Day 945 (ECOG 1): M Protein 0.727 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 9.8 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 11 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6.88 mmol/L.
- Day 1,085 (ECOG 1): M Protein 0.888 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.959 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.98 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.4 mmol/L.
- Day 1,204 (ECOG 1): M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.895 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 3.69 mmol/L.
- Day 1,281 (ECOG 1): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.843 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.02 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day -20: Weight: 86 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1569_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1569_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
